Surgical pathology report (de-identified scan), TCGA case TCGA-66-2793, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2793-01A (Primary Tumor).

Material examined:

Left lung, among others

Clinical diagnosis and question

Adenocarcinoma right central, pleural effusion. TNM?

REPORT ON FINDINGS**Macroscopy**

1.) Inflated, fixed right lung measuring 17 x 13 cm and up to 27 cm high, central bronchus resection plane located 2 cm proximal to the bifurcation of the upper lobe bronchus. Pleura with extensive grayish-yellow coating and, especially in the medial region, with ragged plaques and adhesion residue, in the dorsolateral region over segment 1 a 13 x 8 cm area of parietal pleura is in parts extensively adhesive, in parts loosely attached. Upper pleural fissure completely obliterated. Middle lobe reduced in size and largely occupied by parts of a tumor, max. 9.5 cm in size, predominantly with clear and arcuate demarcation, extending to adjacent sections of the upper lobe and to central sections of the lower lobe. Extension right up to the hilar resection surface and the paracentral medial pleura above the upper lobe and also via the middle and lower lobe in the region of the lower pleural fissure. Involvement of several gray to blackish nodes, 1.5 cm in size, and narrowing of central blood vessels by the tumor. Invasion of the pulmonary vein to within the proximity of the resection margin. Wall infiltration and narrowing of lumen of the intermediate bronchus, whose mucosa shows areas of polypous protrusion above the tumor. Sections of middle lobe bronchi completely obstructed by the tumor tissue. Peripheral middle lobe bronchi markedly dilated and filled with thick mucus, parenchyma in the tumor environment, especially in the middle lobe, shows seam-like area of induration and patchy brownish-yellow discoloration. In S2 a 4 cm area of induration with an irregular contour and brownish-red discoloration. In the pulmonary artery a 2 cm long cylindrical, focal thrombus adhering to the wall.

2.) Pleura: flat or membranous specimen measuring 6.5 x 4.5 cm and up to 0.3 cm thick, surface turbid and in parts patchy brownish, in parts grayish-yellow.

3.) Subcarinal LN (station 7): 0.3 cm lesioned node or node part.

4.) Low paratracheal LN (station 4) right: 1.5 cm fatty specimen, containing at least two lesioned nodes or node parts, 1 cm and 0.4 cm in size.

5.) Hilar LN (station 10) left: 0.5 cm lesioned node with some surrounding tissue.

6.) Low paratracheal LN (station 4) left: 1 cm lesioned node or node part with some surrounding tissue.

Examined:

1a: Tumor with rest of parenchyma. 1b: tumor with intermediate bronchus. 1: pulmonary artery with thrombus. 1d: tumor with hilar resection surface (color-marked). 1e: tumor with paracentral pleura. 1f: lower pleural fissure (lower lobe part color-marked). 1g: upper pleural fissure (upper lobe part color-marked). 1h: middle lobe peripheral. 1i: S1 with pleural adhesion. 1j: central bronchus resection plane and resection margins of vessels. 1k + 1: tumor in pulmonary vein. m: induration area S2.

2.) 5 sections.

3.) - 6.) All material (in 4.) node isolated, in 6.) preparation halved).

18 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

Source: NCI Genomic Data Commons file 41f5a251-a115-4794-9f96-96f989ffb70b (TCGA-66-2793.C2A1AD10-926C-4BAB-9A34-467B3496A453.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).